CGCI case HTMCP-02-07-01065 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f7f769af-992f-4255-9a29-a04ea53f3118

Demographics
Sex at birth: male; Race: black or african american; Age at index: 65 years; Vital status: Dead; Days to death: 332 days.

Diagnoses (1)
1. Carcinoma, undifferentiated, NOS: ICD-O-3 morphology code: 8020/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 65.2 years (23,831 days); Year of diagnosis: 2014; Method of diagnosis: Core Biopsy; AJCC clinical T: TX; AJCC clinical N: N3; AJCC clinical M: M1b; AJCC clinical stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 332 days.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 0 days; ECOG performance status: 2.
- Days to follow up: 332 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day -757.

Molecular and laboratory tests
- NKX2-1 (IHC): Positive.

Other clinical attributes
- Day -757: Risk factors: HIV/AIDS.
- Day -757: Comorbidities: HIV/AIDS.
- Day 0: Weight: 69.3 kg; Height: 174 cm; BMI: 22.9; CD4 count: 38; Haart treatment indicator: Yes.
- Day 0: Cdc hiv risk factors: Heterosexual Contact.
- Day 332: Nadir CD4 count: 33.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 20.

Biospecimens (4 samples)
- Samples HTMCP-02-07-01065-01Z, HTMCP-02-07-01065-06Z (2 with the same recorded description): Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-07-01065-06A: Tissue type: Tumor; Tumor descriptor: Metastatic.
- Sample HTMCP-02-07-01065-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Site of primary tumor other: Left Cervical node; Histologic diagnosis: Other - Undifferentiated carcinoma; Tumor status: With tumor; Tobacco smoking age started: 14; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tobacco smoking history indicator: 2.
- History of disease: Year of HIV diagnosis: 2012; Hbv test results: Negative; Hcv test results: Negative; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes.
- Primary pathology: Method initial path diagnosis: Other method, specify:; Days from index date to tumor sample procurement: 32.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-07-01065-06A-01E-11051:
- % tumour top: 90
- % tumour bottom: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-07-01065-06A-01S-11051:
- % tumour top: 90
- % tumour bottom: 90
